Somatic mutation profile of tumor specimen MMRF_1977_1_BM_CD138pos (aliquot MMRF_1977_1_BM_CD138pos_T1_KBS5U_L07266) from MMRF case MMRF_1977, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: male; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 45.4 years (16,572 days).
Specimen MMRF_1977_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f070a61e-0a75-4567-b2eb-b69a692fb66e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_1977_1_PB_Whole (Blood Derived Normal), aliquot MMRF_1977_1_PB_Whole_C3_KBS5U_L07267; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/bfd3856c-5110-422b-9972-77c6959d7b11

The open-access MAF lists 59 somatic variants for this specimen: 23 protein-altering or splice-affecting, 8 silent, 28 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 19, 3'UTR 14, Silent 8, Intron 6, 5'UTR 3, Frame Shift Del 2, RNA 2, 5'Flank 2, Splice Region 1, Nonsense Mutation 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AUTS2 | c.3356G>A p.R1119Q | Missense Mutation (SNP) | VAF 12/82 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV61425444; called by muse, varscan2
- CYP8B1 | c.853G>A p.G285R | Missense Mutation (SNP) | VAF 13/229 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100295989, COSV100296105; called by muse, mutect2
- IGHV1-69D | c.215C>T p.P72L | Missense Mutation (SNP) | VAF 85/116 reads (73%) | SIFT deleterious (0.02); PolyPhen benign (0.168); catalogued as rs1205376458; called by muse, varscan2
- IGHV2-70 | c.163G>A p.V55M | Missense Mutation (SNP) | VAF 73/123 reads (59%) | SIFT tolerated (0.11); PolyPhen benign (0.433); catalogued as rs372630587; called by muse, varscan2
- PLB1 | c.4147C>T p.R1383* | Nonsense Mutation (SNP) | VAF 25/74 reads (34%) | catalogued as rs758859271; called by muse, mutect2, varscan2
- RASA2 | c.2275_2276del p.E759Kfs*12 | Frame Shift Del (DEL) | VAF 7/42 reads (17%) | catalogued as rs756946687; called by mutect2, pindel, varscan2
- TENT5C | c.725G>A p.G242E | Missense Mutation (SNP) | VAF 20/114 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.573); catalogued as rs1198478524; called by muse, varscan2
- ADGRF3 | c.3118G>A p.A1040T (on ENST00000311519 / NM_001145168.1; = p.A841T on NM_153835.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 97/204 reads (48%) | SIFT tolerated (0.13); PolyPhen benign (0.033); called by muse, mutect2, varscan2
- ANGPT2 | c.4T>C p.W2R | Missense Mutation (SNP) | VAF 26/59 reads (44%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.77); called by muse, mutect2, varscan2
- ATP6V0B | c.591+4A>C | Splice Region (SNP) | VAF 106/215 reads (49%) | called by muse, mutect2
- COL16A1 | c.4250C>T p.P1417L | Missense Mutation (SNP) | VAF 29/65 reads (45%) | SIFT tolerated (0.6); PolyPhen benign (0.388); called by muse, mutect2, varscan2
- DNAH17 | c.4060C>A p.Q1354K | Missense Mutation (SNP) | VAF 7/95 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); called by muse, mutect2
- DOCK3 | c.1900G>C p.G634R | Missense Mutation (SNP) | VAF 63/240 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); called by muse, mutect2, varscan2
- DOCK3 | c.1901G>T p.G634V | Missense Mutation (SNP) | VAF 63/239 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.963); called by muse, mutect2, varscan2
- FAT2 | c.3648C>A p.D1216E | Missense Mutation (SNP) | VAF 48/178 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- IGHA1 | c.620C>G p.A207G | Missense Mutation (SNP) | VAF 53/174 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.237); called by muse, mutect2, varscan2
- MRPL32 | c.83T>C p.L28P | Missense Mutation (SNP) | VAF 41/88 reads (47%) | SIFT tolerated (0.14); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- MRPS31 | c.514A>C p.T172P | Missense Mutation (SNP) | VAF 48/88 reads (55%) | SIFT tolerated (0.12); PolyPhen benign (0.348); called by muse, mutect2, varscan2
- PAPPA2 | c.2665A>T p.T889S | Missense Mutation (SNP) | VAF 31/61 reads (51%) | SIFT tolerated (0.17); PolyPhen benign (0.168); called by muse, mutect2, varscan2
- PRDM7 | c.443C>T p.A148V | Missense Mutation (SNP) | VAF 22/50 reads (44%) | SIFT tolerated (0.31); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- TENT5C | c.608_609del p.S203* | Frame Shift Del (DEL) | VAF 14/114 reads (12%) | called by pindel, varscan2
- UGGT2 | c.467T>A p.L156Q | Missense Mutation (SNP) | VAF 24/41 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- ZBTB5 | c.1667A>G p.N556S | Missense Mutation (SNP) | VAF 73/243 reads (30%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.051); called by muse, mutect2, varscan2
- CDH11 | c.1794C>T p.N598= | Silent (SNP) | VAF 48/108 reads (44%) | catalogued as rs563299959, COSV51764281, COSV51767424; called by muse, mutect2, varscan2
- HDGFL1 | c.729G>A p.P243= | Silent (SNP) | VAF 59/103 reads (57%) | catalogued as rs968484120, COSV100014565; called by muse, mutect2, varscan2
- HOMER2 | c.210G>A p.T70= | Silent (SNP) | VAF 26/80 reads (33%) | catalogued as rs139619821, COSV58488227; called by muse, mutect2, varscan2
- IGHV2-70 | c.66C>G p.T22= | Silent (SNP) | VAF 47/113 reads (42%) | catalogued as rs368498453; called by muse, varscan2
- OR52H1 | c.642T>C p.I214= (on ENST00000322653; = p.I220= on NM_001005289.1) | Silent (SNP) | VAF 77/156 reads (49%) | called by muse, mutect2, varscan2
- OR5D13 | c.456A>T p.T152= | Silent (SNP) | VAF 16/361 reads (4%) | called by muse, mutect2
- PRR5-ARHGAP8 | c.1005G>A p.K335= (on ENST00000352766; = p.K256= on NM_181334.5) | Silent (SNP) | VAF 65/124 reads (52%) | catalogued as COSV61232547; called by muse, mutect2, varscan2
- TLL1 | c.1359C>T p.G453= | Silent (SNP) | VAF 68/141 reads (48%) | called by muse, mutect2, varscan2
- ACSS1 | c.*679C>A | 3'UTR (SNP) | VAF 54/102 reads (53%) | called by muse, mutect2
- CACNA2D1 | chr7:81947371 G>T | 3'Flank (SNP) | VAF 60/122 reads (49%) | called by muse, mutect2, varscan2
- CCND2 | c.*1358A>T | 3'UTR (SNP) | VAF 9/80 reads (11%) | catalogued as rs1286939073, COSV54224367; called by muse, varscan2
- CRP | c.*574C>T | 3'UTR (SNP) | VAF 45/108 reads (42%) | called by muse, mutect2, varscan2
- DNAH2 | c.6348+12G>T | Intron (SNP) | VAF 35/62 reads (56%) | called by muse, mutect2, varscan2
- FAM183BP | n.751G>A | RNA (SNP) | VAF 189/402 reads (47%) | called by muse, mutect2, varscan2
- GADL1 | c.*1247G>A | 3'UTR (SNP) | VAF 20/72 reads (28%) | called by muse, mutect2, varscan2
- GFRA2 | c.41-35G>A | Intron (SNP) | VAF 119/255 reads (47%) | catalogued as rs1479269170, COSV60778971; called by muse, mutect2, varscan2
- IGLV1-41 | n.272G>C | RNA (SNP) | VAF 36/80 reads (45%) | called by muse, varscan2
- KIAA1549 | c.*3212G>T | 3'UTR (SNP) | VAF 70/130 reads (54%) | called by muse, mutect2
- LRRC75A | c.*1490C>T | 3'UTR (SNP) | VAF 68/133 reads (51%) | called by muse, mutect2, varscan2
- MAT2A | c.-89A>G | 5'UTR (SNP) | VAF 20/51 reads (39%) | called by muse, mutect2, varscan2
- MCMDC2 | c.*1897C>T | 3'UTR (SNP) | VAF 42/87 reads (48%) | catalogued as rs756389293; called by muse, mutect2, varscan2
- MUC19 | chr12:40527680 C>T | 5'Flank (SNP) | VAF 56/118 reads (47%) | called by muse, mutect2, varscan2
- NCOR2 | c.3382-130C>T | Intron (SNP) | VAF 21/35 reads (60%) | catalogued as rs899449058; called by muse, mutect2, varscan2
- NPY2R | c.*813C>G | 3'UTR (SNP) | VAF 37/77 reads (48%) | called by muse, mutect2, varscan2
- PGR | c.*2558G>T | 3'UTR (SNP) | VAF 100/158 reads (63%) | called by muse, mutect2, varscan2
- RBM34 | c.657+151A>G | Intron (SNP) | VAF 12/20 reads (60%) | called by muse, mutect2, varscan2
- RBM48 | c.*1045A>G | 3'UTR (SNP) | VAF 57/139 reads (41%) | called by muse, mutect2, varscan2
- RELA | c.*633G>T | 3'UTR (SNP) | VAF 85/129 reads (66%) | called by muse, mutect2, varscan2
- RGS11 | c.371-50G>A | Intron (SNP) | VAF 27/44 reads (61%) | catalogued as rs191294588; called by muse, mutect2, varscan2
- RND3 | c.*1587T>C | 3'UTR (SNP) | VAF 59/127 reads (46%) | called by muse, mutect2, varscan2
- SYBU | chr8:109646014 G>A | 5'Flank (SNP) | VAF 25/61 reads (41%) | called by muse, mutect2, varscan2
- TMED5 | c.*708A>G | 3'UTR (SNP) | VAF 9/53 reads (17%) | called by muse, mutect2, varscan2
- TRAM1 | c.-163C>T | 5'UTR (SNP) | VAF 32/54 reads (59%) | catalogued as rs1411196948; called by muse, mutect2, varscan2
- WAPL | c.*203C>T | 3'UTR (SNP) | VAF 50/94 reads (53%) | called by muse, mutect2, varscan2
- ZFP36 | c.-6C>T | 5'UTR (SNP) | VAF 66/282 reads (23%) | catalogued as COSV50530599, COSV99953891; called by muse, mutect2, varscan2
- ZNF746 | c.520+1273G>A | Intron (SNP) | VAF 10/140 reads (7%) | catalogued as rs878972025; called by muse, mutect2
